Somatic mutation profile of tumor specimen MP2PRT-PAPXVZ-TMP1-A (aliquot MP2PRT-PAPXVZ-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PAPXVZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,697 days).
Specimen MP2PRT-PAPXVZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe019179-6670-44bf-a7cd-04b1def841a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPXVZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPXVZ-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ea6c08f-c685-40de-8429-dbae98801331

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTL | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 34/646 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759833663, COSV60904606; called by muse, mutect2
- DNAH5 | c.7544C>T p.T2515M | Missense Mutation (SNP) | VAF 108/1208 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV54224881; called by muse, mutect2
- ERVV-2 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.646); catalogued as COSV74153479; called by mutect2, varscan2
- GLDC | c.1925C>T p.T642M | Missense Mutation (SNP) | VAF 155/473 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs141153261, COSV58679601; called by muse, mutect2, varscan2
- MED16 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 529/1158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs773051100; called by muse, mutect2, varscan2
- MTOR | c.5920T>C p.Y1974H | Missense Mutation (SNP) | VAF 152/418 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63869915; called by muse, mutect2, varscan2
- NCAN | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 76/893 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV53053738, COSV53059897, COSV53059942; called by muse, mutect2
- RNF20 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs771488880, COSV66660847; called by muse, mutect2, varscan2
- RPH3A | c.245G>A p.R82H (on ENST00000389385 / NM_001143854.2; = p.R78H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 172/401 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs141736304, COSV66992865; called by muse, mutect2, varscan2
- SLC4A3 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 55/889 reads (6%) | catalogued as COSV56092242; called by muse, mutect2
- SORCS1 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 28/1048 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV53895310; called by muse, mutect2
- C1orf94 | c.830G>T p.G277V (on ENST00000488417 / NM_001134734.2; = p.G87V on NM_032884.5) | Missense Mutation (SNP) | VAF 30/839 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- HMGB1 | c.541dup p.S181Kfs*11 | Frame Shift Ins (INS) | VAF 43/139 reads (31%) | called by mutect2, pindel, varscan2
- LONRF3 | c.1813T>C p.F605L (on ENST00000371628 / NM_001031855.3; = p.F564L on NM_024778.5) | Missense Mutation (SNP) | VAF 60/710 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2
- STK26 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 332/553 reads (60%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.153); called by muse, varscan2
- ABCC8 | c.4515C>T p.D1505= | Silent (SNP) | VAF 247/619 reads (40%) | catalogued as rs751591418, CM107102, CM112799, COSV56845944; called by muse, mutect2, varscan2
- MUC2 | c.2121C>T p.D707= | Silent (SNP) | VAF 437/931 reads (47%) | catalogued as rs563740566; called by muse, mutect2, varscan2
- PHEX | c.1032G>A p.P344= | Silent (SNP) | VAF 92/1144 reads (8%) | catalogued as rs1485980861; called by muse, mutect2
